Somatic mutation profile of tumor specimen TCGA-CN-6013-01A (aliquot TCGA-CN-6013-01A-11D-1683-08) from TCGA case TCGA-CN-6013, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 56.7 years (20,703 days).
Specimen TCGA-CN-6013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd4ed5e2-a36b-473a-86d5-de06ac41ae7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6013-10A (Blood Derived Normal), aliquot TCGA-CN-6013-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60579a23-885a-4020-be9c-3b39ae8df010

The open-access MAF lists 200 somatic variants for this specimen: 154 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 43, Nonsense Mutation 14, Frame Shift Del 2, Splice Region 2, 5'Flank 1, Intron 1, Translation Start Site 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD17B | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100330293; called by muse, mutect2, varscan2
- ACER2 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100575880; called by muse, mutect2, varscan2
- ADGRD1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99897021; called by muse, mutect2, varscan2
- ADGRL1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763203395, COSV100529809; called by muse, mutect2, varscan2
- ASPM | c.9493C>G p.H3165D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99660147, COSV99661094; called by muse, mutect2, varscan2
- BARD1 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99639846; called by muse, mutect2, varscan2
- BICD1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1322401627, COSV99862976; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2524C>T p.L842F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV100863937; called by muse, mutect2, varscan2
- C2CD5 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100449017, COSV61728056; called by muse, mutect2
- CD209 | c.1128C>G p.I376M | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99214390; called by muse, mutect2, varscan2
- CDH10 | c.2167C>A p.L723I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100050993, COSV52578143; called by muse, mutect2, varscan2
- CFAP206 | c.1723C>G p.P575A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100849728; called by muse, mutect2, varscan2
- CLCN3 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100641828; called by muse, mutect2, varscan2
- CLSTN2 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV71726327; called by muse, mutect2, varscan2
- CNGB1 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99210289; called by muse, mutect2
- CNTN1 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.241); catalogued as rs1286090767, COSV100751894; called by mutect2, varscan2
- COL17A1 | c.1170del p.E391Kfs*12 | Frame Shift Del (DEL) | VAF 41/117 reads (35%) | catalogued as rs769586532; called by mutect2, pindel, varscan2
- COL4A5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.025); catalogued as COSV100089846; called by muse, mutect2, varscan2
- COL6A1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs773845144, COSV100719798; called by muse, mutect2, varscan2
- COQ8B | c.773T>G p.L258R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99699624; called by muse, mutect2, varscan2
- CSMD3 | c.7535T>G p.L2512R (on ENST00000297405 / NM_001363185.1; = p.L2408R on NM_052900.3) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52266417, COSV52340017, COSV99847242; called by muse, mutect2, varscan2
- CTR9 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1211230732, COSV63729643; called by muse, mutect2, varscan2
- CXXC1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99497219; called by muse, mutect2, varscan2
- DIP2B | c.2764C>G p.L922V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV99999340; called by muse, mutect2, varscan2
- DNAH3 | c.3850C>G p.Q1284E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99770543; called by muse, mutect2, varscan2
- DOP1A | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV99382908; called by muse, mutect2, varscan2
- DSCAM | c.5461G>A p.A1821T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1208234992, COSV68032312; called by muse, mutect2, varscan2
- EIF3I | c.958G>A p.E320K (on ENST00000373586; = p.E322K on NM_003757.3) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV100753512; called by muse, mutect2, varscan2
- EPHA7 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.119); catalogued as COSV100994340; called by muse, mutect2, varscan2
- ERCC4 | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100319106, COSV61313986; called by muse, mutect2
- ERICH3 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100445712; called by muse, mutect2, varscan2
- F5 | c.6481G>A p.G2161R | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100889232; called by muse, varscan2
- FAM24B | c.93-1G>C p.X31_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100158983; called by muse, mutect2, varscan2
- FLII | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV58946661; called by muse, mutect2, varscan2
- FSIP2 | c.16045G>A p.D5349N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.737); catalogued as COSV100556467; called by muse, varscan2
- FSIP2 | c.16055C>T p.S5352F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100556469; called by muse, varscan2
- GAB3 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100850700; called by muse, mutect2, varscan2
- GANC | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | PolyPhen benign (0.005); catalogued as COSV100531236; called by muse, mutect2, varscan2
- H2AC17 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs1229194273, COSV100377726; called by muse, mutect2, varscan2
- HS2ST1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.439); catalogued as COSV100777851; called by muse, mutect2, varscan2
- IFIH1 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV99718883; called by muse, mutect2, varscan2
- IGSF10 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs950097633, COSV99194410; called by muse, mutect2, varscan2
- INSC | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV101089669, COSV65411256; called by muse, mutect2, varscan2
- IQCG | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs765829254, COSV99502695; called by muse, mutect2, varscan2
- IQCH | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV100246324; called by muse, mutect2, varscan2
- ITPR2 | c.6553G>A p.E2185K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101190161; called by muse, mutect2, varscan2
- KCNB2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as rs140088625, COSV73050022; called by muse, mutect2, varscan2
- KEL | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs537189264, COSV62333479; called by muse, mutect2, varscan2
- KIF6 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377245127; called by muse, mutect2, varscan2
- KLHL1 | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100918125; called by muse, mutect2, varscan2
- KMT2A | c.4897C>T p.R1633* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as CM1514073, COSV63288100; called by muse, mutect2, varscan2
- KMT2C | c.3966G>A p.W1322* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100076338; called by muse, mutect2, varscan2
- KRT4 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as rs1284159580, COSV104395655, COSV53405642; called by muse, mutect2, varscan2
- LPIN2 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858965; called by muse, mutect2, varscan2
- MAP3K19 | c.3904C>T p.R1302C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs760518747, COSV100208400; called by muse, mutect2
- MAST2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs753056600, COSV100788756; called by muse, mutect2, varscan2
- MATN3 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV99853509; called by muse, mutect2, varscan2
- MBIP | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs774272761, COSV100576832; called by muse, mutect2, varscan2
- MCU | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as rs1331392304, COSV100849266; called by muse, mutect2, varscan2
- MEFV | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs758072895, COSV99561278; called by muse, mutect2, varscan2
- MX1 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99912832; called by muse, mutect2, varscan2
- MYH1 | c.2637A>C p.E879D | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99876850; called by muse, mutect2, varscan2
- MYH10 | c.5008G>A p.E1670K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99346335; called by muse, mutect2, varscan2
- MYH9 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99338759; called by muse, mutect2, varscan2
- NAV1 | c.5620C>T p.Q1874* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99819665; called by muse, mutect2
- NCAM2 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV53078824; called by muse, mutect2, varscan2
- NEK1 | c.1944G>C p.K648N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV101455879; called by muse, mutect2, varscan2
- NGDN | c.144G>A p.K48= | Splice Region (SNP) | VAF 14/63 reads (22%) | catalogued as COSV101238924; called by muse, mutect2, varscan2
- NHLRC3 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV101099037; called by muse, mutect2, varscan2
- NID2 | c.2260G>C p.D754H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV99357239; called by mutect2, varscan2
- NLRP13 | c.390G>A p.G130= | Splice Region (SNP) | VAF 9/53 reads (17%) | catalogued as COSV61621323; called by muse, mutect2, varscan2
- NUDT11 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV65665503; called by muse, mutect2, varscan2
- NXNL2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as rs1297897413, COSV101018392; called by muse, mutect2
- PCDH11X | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100015193; called by muse, mutect2, varscan2
- PCNX1 | c.4891G>A p.E1631K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53095882; called by muse, mutect2, varscan2
- PCSK2 | c.1761G>A p.W587* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99360681; called by muse, mutect2, varscan2
- PEAK1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs761143003, COSV56930324; called by muse, mutect2, varscan2
- PGM1 | c.436A>T p.K146* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100936674; called by muse, mutect2, varscan2
- PIK3C2G | c.3938C>T p.S1313L (on ENST00000676171; = p.S1272L on NM_004570.5) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.099); catalogued as COSV56809028; called by muse, mutect2, varscan2
- PLCB3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV54188507; called by muse, mutect2, varscan2
- PLSCR4 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100724349; called by muse, mutect2, varscan2
- POPDC2 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51739677, COSV51743126; called by muse, mutect2, varscan2
- PRC1 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV62697022; called by muse, mutect2, varscan2
- PRKD1 | c.1750T>A p.F584I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100121489; called by muse, mutect2
- PTCHD1 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV101037998, COSV65063144; called by muse, mutect2, varscan2
- RAB5A | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99811171; called by muse, mutect2, varscan2
- RAD21 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV99815614; called by muse, mutect2, varscan2
- RASAL1 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs61759863, COSV55661648; called by muse, mutect2, varscan2
- RBM26 | c.2992G>A p.E998K (on ENST00000438737 / NM_001366735.2; = p.E971K on NM_022118.5) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99936026, COSV99936610; called by muse, mutect2, varscan2
- RBP3 | c.2597C>T p.T866M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782152099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RETREG2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV99811703; called by muse, mutect2, varscan2
- RFC2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as COSV99278100; called by muse, mutect2, varscan2
- RP1 | c.788T>A p.I263K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs1347603964, COSV99608821; called by muse, mutect2, varscan2
- RPL26 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99549542; called by muse, mutect2, varscan2
- RPL37 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99947715; called by muse, mutect2, varscan2
- RPL37 | c.19T>A p.S7T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99947716; called by muse, mutect2, varscan2
- RSPH4A | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV99994299; called by muse, mutect2, varscan2
- RUSC2 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100770731, COSV100770875; called by muse, mutect2, varscan2
- SAMD13 | c.34G>C p.E12Q (on ENST00000370671; = p.E6Q on NM_001010971.3) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); catalogued as COSV101043314, COSV65745248; called by muse, mutect2, varscan2
- SEC23IP | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100957087; called by muse, mutect2, varscan2
- SEC23IP | c.2561G>C p.R854T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100957089; called by muse, mutect2, varscan2
- SEMA3E | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100319590; called by muse, mutect2, varscan2
- SEMA4A | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100740736; called by muse, mutect2, varscan2
- SETX | c.6316G>A p.E2106K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.438); catalogued as rs774547328, COSV99810885; called by muse, varscan2
- SHANK3 | c.4346C>G p.S1449C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53183583; called by muse, mutect2
- SLC12A5 | c.172G>A p.E58K (on ENST00000454036 / NM_001134771.2; = p.E35K on NM_020708.5) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99716818; called by muse, mutect2, varscan2
- SLC12A9 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 34/394 reads (9%) | catalogued as COSV99308193, COSV99308310; called by muse, mutect2
- SLC6A4 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV99911593; called by muse, mutect2, varscan2
- SLITRK6 | c.1723A>G p.M575V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs754132796, COSV101233295; called by muse, mutect2, varscan2
- SMAD3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs762012589, CM158151, COSV100528797; called by muse, mutect2, varscan2
- SOX5 | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100508140; called by muse, varscan2
- SPG7 | c.1903G>A p.E635K (on ENST00000268704; = p.E642K on NM_003119.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202120338, COSV51954483; called by muse, mutect2
- SPSB2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs368362101, COSV99222991; called by muse, mutect2
- SPTB | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144624027; called by muse, mutect2, varscan2
- SPTBN1 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.889); catalogued as COSV100443388; called by muse, mutect2, varscan2
- STX4 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100572990, COSV58269215; called by muse, mutect2, varscan2
- SUN2 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99325839; called by muse, mutect2, varscan2
- SYS1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as rs374993970; called by mutect2, varscan2
- TAFA5 | c.389C>T p.T130M (on ENST00000402357 / NM_001082967.3; = p.T123M on NM_015381.7) | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs776805180, COSV60991275; called by muse, mutect2, varscan2
- TENM1 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100950914; called by muse, varscan2
- TENM1 | c.1955G>T p.G652V | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950919, COSV64429123; called by muse, varscan2
- THOC1 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99863613; called by muse, mutect2, varscan2
- TMCC1 | c.1408C>T p.R470W (on ENST00000393238 / NM_001349268.2; = p.R146W on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100261299; called by muse, varscan2
- TP53BP1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99781479; called by muse, mutect2, varscan2
- TRIM45 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99868731; called by muse, varscan2
- TRIM45 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs758511556, COSV99868247, COSV99868735; called by muse, varscan2
- TRRAP | c.10296G>A p.M3432I (on ENST00000359863 / NM_001244580.1; = p.M3403I on NM_003496.3) | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100722941; called by muse, mutect2, varscan2
- TSPOAP1 | c.5479G>A p.E1827K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99272671; called by muse, mutect2, varscan2
- TTN | c.62728G>A p.D20910N (on ENST00000591111; = p.D13486N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.183); catalogued as COSV100629361; called by muse, mutect2
- TTN | c.36035A>C p.E12012A (on ENST00000591111; = p.E4588A on NM_003319.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | PolyPhen possibly damaging (0.616); catalogued as COSV100629362; called by muse, mutect2, varscan2
- TTN | c.34976A>C p.K11659T (on ENST00000591111; = p.K10732T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | PolyPhen possibly damaging (0.447); catalogued as COSV59873171, COSV60030664; called by muse, mutect2, varscan2
- ULK1 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100417269; called by muse, mutect2, varscan2
- USH2A | c.3388G>A p.V1130M | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100242467; called by muse, mutect2, varscan2
- WDR7 | c.3379A>G p.I1127V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs375430949; called by muse, mutect2, varscan2
- XPA | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs1179193179, COSV100910345; called by muse, mutect2
- ZFHX3 | c.10583C>T p.S3528L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs781184186, COSV51731993; called by muse, mutect2
- ZFP36 | c.593C>G p.S198C (on ENST00000594442; = p.S192C on NM_003407.5) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99954005; called by muse, mutect2, varscan2
- ZIC3 | c.1309A>C p.N437H | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV99799483; called by muse, mutect2, varscan2
- ZNF12 | c.898A>T p.N300Y (on ENST00000405858 / NM_016265.4; = p.N262Y on NM_006956.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.748); catalogued as COSV100703880; called by muse, mutect2, varscan2
- ZNF12 | c.616C>G p.L206V (on ENST00000405858 / NM_016265.4; = p.L168V on NM_006956.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100703882; called by muse, mutect2, varscan2
- ZNF189 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.502); catalogued as COSV52274435, COSV99407310; called by muse, mutect2, varscan2
- ZNF300 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51032809; called by muse, mutect2, varscan2
- ZNF37A | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs767682976, COSV61073219; called by muse, mutect2, varscan2
- ZNF549 | c.88G>A p.E30K (on ENST00000376233 / NM_001199295.2; = p.E17K on NM_153263.2) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV99558794; called by muse, mutect2, varscan2
- ZNF557 | c.100G>A p.G34S (on ENST00000414706 / NM_001044388.2; = p.G41S on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99422753; called by muse, mutect2, varscan2
- ZNF785 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.67); catalogued as rs771491092, COSV101235783, COSV101235809; called by muse, mutect2, varscan2
- ZSCAN25 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.758); catalogued as COSV99500727; called by muse, mutect2, varscan2
- ACACA | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NRBP1 | c.906del p.E302Dfs*46 | Frame Shift Del (DEL) | VAF 18/149 reads (12%) | called by pindel*, varscan2
- SLC9B1 | c.1431C>G p.I477M | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMCC1 | c.1409G>T p.R470L (on ENST00000393238 / NM_001349268.2; = p.R146L on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); called by muse, varscan2
- ADAMTS2 | c.2355C>T p.S785= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs771411876, COSV99283821; called by muse, mutect2, varscan2
- ADAMTS6 | c.2763A>G p.T921= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV100068601; called by muse, mutect2, varscan2
- ANGPTL1 | c.186G>A p.G62= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV99328357; called by muse, mutect2
- CBX2 | c.1110C>T p.L370= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV53970230; called by muse, mutect2, varscan2
- CDK17 | c.57T>C p.D19= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1038829271, COSV99703075; called by muse, mutect2, varscan2
- CHRD | c.2205G>A p.T735= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99200788; called by muse, mutect2, varscan2
- COL6A3 | c.2757G>A p.A919= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs115874872; called by muse, mutect2, varscan2
- CPED1 | c.114G>C p.S38= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100121470; called by muse, mutect2, varscan2
- CPNE4 | c.819G>A p.K273= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs371941468, COSV70191252; called by muse, mutect2, varscan2
- CRYBG1 | c.4320C>T p.V1440= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as COSV100954617; called by muse, mutect2, varscan2
- CYP3A7 | c.1395C>T p.F465= | Silent (SNP) | VAF 25/223 reads (11%) | catalogued as COSV100312883; called by muse, mutect2, varscan2
- DNAJB2 | c.867C>T p.A289= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99834337; called by muse, varscan2
- DOCK4 | c.4080C>T p.I1360= | Silent (SNP) | VAF 28/309 reads (9%) | catalogued as rs529221240, COSV101445654; called by muse, mutect2
- DOP1A | c.3600C>T p.S1200= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99382910; called by muse, mutect2, varscan2
- ECHDC2 | c.525G>A p.Q175= (on ENST00000371522 / NM_001198961.2; = p.Q144= on NM_018281.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs756125045, COSV100597760; called by muse, mutect2, varscan2
- EYS | c.507G>A p.V169= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100677149, COSV60985080; called by muse, mutect2, varscan2
- FBLN5 | c.354G>A p.Q118= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV99969934; called by muse, mutect2, varscan2
- FBXO10 | c.2754C>G p.L918= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs1166265091, COSV99447238; called by muse, mutect2, varscan2
- FUT5 | c.1124G>A p.*375= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV99398901, COSV99398989; called by muse, mutect2, varscan2
- GOLGA2 | c.2553G>A p.E851= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV57849550; called by muse, mutect2, varscan2
- HSPA9 | c.360C>T p.T120= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99785673; called by muse, mutect2, varscan2
- IL2RB | c.162G>A p.L54= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99345133; called by muse, varscan2
- IRF7 | c.1254C>T p.F418= (on ENST00000397566; = p.F405= on NM_001572.5) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs781777277, COSV99213443; called by muse, mutect2, varscan2
- JAG1 | c.3399G>A p.T1133= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs780936422, COSV99653522; called by muse, mutect2, varscan2
- KCNMA1 | c.1413C>T p.L471= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs903717178, COSV99699583; called by muse, mutect2, varscan2
- KCNMB1 | c.123C>T p.L41= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV51133258, COSV99212007; called by muse, mutect2, varscan2
- OR10K2 | c.312C>T p.F104= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV59222060; called by muse, mutect2, varscan2
- OR2M7 | c.189C>T p.L63= | Silent (SNP) | VAF 50/317 reads (16%) | catalogued as COSV100522681; called by muse, mutect2, varscan2
- OR4P4 | c.375C>T p.C125= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100111858; called by muse, mutect2
- OSBP2 | c.966C>T p.L322= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100213717; called by muse, mutect2, varscan2
- PFKFB3 | c.246C>T p.Y82= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100432366; called by muse, mutect2, varscan2
- PLXND1 | c.3282C>T p.F1094= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs754031616, COSV100140375; called by muse, mutect2, varscan2
- PSD | c.1743C>T p.G581= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99193919; called by muse, mutect2
- PTK2 | c.192C>G p.V64= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100571195; called by muse, mutect2, varscan2
- RPS6KA2 | c.246C>T p.S82= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs748386172, COSV99692082; called by muse, mutect2, varscan2
- SLCO1A2 | c.1998G>A p.L666= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100261760; called by muse, mutect2, varscan2
- SYNE1 | c.23241C>T p.I7747= (on ENST00000367255 / NM_182961.4; = p.I7676= on NM_033071.3) | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV99578132; called by muse, mutect2, varscan2
- VCAN | c.4248C>T p.L1416= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs758617685, COSV54104655; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WDR35 | c.1860C>T p.F620= (on ENST00000345530 / NM_001006657.2; = p.F609= on NM_020779.4) | Silent (SNP) | VAF 44/202 reads (22%) | catalogued as COSV99853508; called by muse, mutect2, varscan2
- ZFHX3 | c.1071C>T p.L357= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs1184474197, COSV51717959, COSV51730352; called by muse, mutect2, varscan2
- ZNF333 | c.1731C>T p.L577= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99469546; called by muse, mutect2, varscan2
- ZNF527 | c.429G>A p.A143= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs754915502, COSV62230779; called by muse, mutect2, varscan2
- ZNF91 | c.489C>T p.F163= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100323437; called by muse, mutect2, varscan2
- HNMT | c.190+11130G>T | Intron (SNP) | VAF 17/106 reads (16%) | catalogued as COSV99699110; called by muse, mutect2, varscan2
- MIR758 | n.76C>T | RNA (SNP) | VAF 24/89 reads (27%) | catalogued as rs755805095; called by muse, mutect2, varscan2
- UCHL5 | chr1:193059978 C>T | 5'Flank (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100814681; called by muse, mutect2, varscan2
